CCDI case PBCUEN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/645906e4-e5b3-4e46-9fa4-1bd4256ee713

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1SXX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1SY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1SYH: Tissue type: Tumor; Specimen type: Solid Tissue.
